Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39R, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39R-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

- 1) DELPHIAN LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 2) LEFT ENLARGED INFERIOR PARATHYROID (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
- 3) THYROID (TOTAL THYROIDECTOMY, CENTRAL NECK DISSECTION):

SPECIMEN TYPE:

10D-0-3

Total thyroidectomy

Carcinoma, papillary, thyroid 8260/3

TUMOR SITE:

Site: thyroid, NOS C73.9

Right lobe

Left lobe

lw
9/14/11

LARGEST TUMOR SIZE: 1.8 centimeters (right lobe).

HISTOLOGIC TYPE:

Papillary carcinoma

FOCALITY:

Multifocal (right and left lobe, right lobe predominantly. Small parenchymal foci in left lobe)

LYMPH NODES:

All 18 lymph nodes are negative for tumor (0/18). Extranodal extension of tumor not identified.

EXTENT OF INVASION

PRIMARY TUMOR:

pT1: Tumor size less than or equal to 2 centimeters

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Involved by invasive carcinoma (right thyroid lobe)

VENOUS/LYMPHATIC INVASION:

Absent

[page 2 of 2]
ADDITIONAL PATHOLOGIC FINDINGS:

lymphocytic thyroiditis

Parathyroid gland tissue present (lateral aspect of right inferior lobe)

Source: NCI Genomic Data Commons file 02f4704d-c88f-4d44-a0ac-678e35b3b012 (TCGA-ET-A39R.637F519B-25EE-4744-8925-5EB307E08B5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).